Somatic mutation profile of tumor specimen TCGA-CH-5737-01A (aliquot TCGA-CH-5737-01A-11D-1576-08) from TCGA case TCGA-CH-5737, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 73.2 years (26,753 days).
Specimen TCGA-CH-5737-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44b4511a-3ac4-4871-afdc-3cba78e05d43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5737-10A (Blood Derived Normal), aliquot TCGA-CH-5737-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0257a62b-b79b-4adc-8162-eb0449867a66

The open-access MAF lists 53 somatic variants for this specimen: 36 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 15, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 1, Nonstop Mutation 1, 3'UTR 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.764_769del p.E255_N256del | In Frame Del (DEL) | VAF 14/30 reads (47%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.355G>T p.V119F | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs139767111, CM001318, COSV64296245, COSV64297577; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.412G>T p.A138S (on ENST00000373394 / NM_001271696.3; = p.A139S on NM_004299.6) | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.052); catalogued as COSV53719829; called by muse, mutect2, varscan2
- ATM | c.8083G>A p.G2695S | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555127166, COSV53741150, COSV53763120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10B | c.2635A>C p.N879H | Missense Mutation (SNP) | VAF 135/329 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV59151502; called by muse, mutect2, varscan2
- C20orf194 | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368282556, COSV52695757; called by muse, mutect2
- CDC7 | c.1688C>A p.A563D | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52310621; called by muse, mutect2
- CDH6 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.604); catalogued as COSV54069558, COSV54072543; called by muse, mutect2, varscan2
- FSCN2 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV58367648; called by muse, mutect2, varscan2
- GNAO1 | c.394T>C p.W132R | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52613812; called by muse, mutect2, varscan2
- H2BC9 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as COSV55099856; called by muse, mutect2
- MICU1 | c.1240G>C p.D414H (on ENST00000361114 / NM_001195518.2; = p.D420H on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV63144818; called by mutect2, varscan2
- MPDZ | c.380A>C p.K127T | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.333); catalogued as COSV59941211; called by muse, mutect2, varscan2
- MSMP | c.152A>C p.K51T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65239500; called by muse, mutect2, varscan2
- MTMR12 | c.239T>G p.F80C | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53784186; called by muse, mutect2
- MTREX | c.516-2A>G p.X172_splice | Splice Site (SNP) | VAF 26/156 reads (17%) | catalogued as rs1013638358, COSV57925820; called by muse, mutect2, varscan2
- OR5B12 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.165); catalogued as rs779411561, COSV56904121; called by muse, mutect2, varscan2
- OTX2 | c.706G>C p.A236P (on ENST00000408990 / NM_172337.3; = p.A244P on NM_021728.4) | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV59766026; called by muse, mutect2, varscan2
- PCDHB2 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV50565755; called by muse, varscan2
- PIP5K1C | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.023); catalogued as rs781188139, COSV58952279; called by muse, mutect2, varscan2
- PON2 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.095); catalogued as COSV56001768; called by muse, mutect2
- PSG8 | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 107/915 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.896); catalogued as COSV60611540, COSV60615785; called by muse, mutect2, varscan2
- REG3G | c.409C>G p.P137A | Missense Mutation (SNP) | VAF 71/274 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.725); catalogued as COSV55448569, COSV55449491; called by muse, mutect2, varscan2
- ROS1 | c.4525-1G>T p.X1509_splice | Splice Site (SNP) | VAF 14/62 reads (23%) | catalogued as COSV63855059; called by muse, mutect2
- SH3TC2 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60463106; called by muse, mutect2, varscan2
- SKAP1 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs573034197, COSV61143949; called by muse, mutect2, varscan2
- SUPT5H | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63239604; called by muse, mutect2, varscan2
- TAF1L | c.2605G>A p.A869T | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1192791006, COSV54259748, COSV54263571; called by muse, mutect2
- TSPAN7 | c.630G>C p.E210D | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.733); catalogued as COSV54528394, COSV54531841; called by muse, mutect2, varscan2
- ZMYM4 | c.2444A>G p.K815R | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs1013785941, COSV58910361; called by muse, mutect2, varscan2
- ZNF98 | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV63334581, COSV63336449; called by muse, varscan2
- CHEK1 | c.1431A>C p.*477Cext*24 (on ENST00000428830 / NM_001114121.2; = p.*477Cext*17 on NM_001274.5) | Nonstop Mutation (SNP) | VAF 6/61 reads (10%) | called by mutect2, varscan2
- FAT2 | c.12499del p.W4167Gfs*32 | Frame Shift Del (DEL) | VAF 48/199 reads (24%) | called by mutect2, pindel, varscan2
- OSER1 | c.95_98del p.S32Lfs*42 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by pindel, varscan2
- PDZRN3 | c.1489dup p.S497Ffs*8 | Frame Shift Ins (INS) | VAF 225/732 reads (31%) | called by mutect2, pindel, varscan2
- RNF31 | c.2013_2014del p.N672Lfs*2 | Frame Shift Del (DEL) | VAF 25/225 reads (11%) | called by mutect2, pindel, varscan2
- CCDC25 | c.414C>G p.V138= | Silent (SNP) | VAF 43/236 reads (18%) | catalogued as COSV62958584, COSV62958706; called by muse, mutect2, varscan2
- CTCFL | c.69G>A p.P23= | Silent (SNP) | VAF 268/819 reads (33%) | catalogued as rs750508860, COSV54770637; called by muse, varscan2
- DDX27 | c.855C>T p.R285= | Silent (SNP) | VAF 120/387 reads (31%) | catalogued as COSV65629656; called by muse, mutect2, varscan2
- DYNC2H1 | c.8859T>G p.L2953= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV62093901; called by muse, mutect2
- HOXD3 | c.216C>T p.S72= | Silent (SNP) | VAF 42/152 reads (28%) | catalogued as COSV50880533; called by muse, varscan2
- KIF5A | c.768C>T p.N256= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as CD083326, COSV54054443; called by muse, mutect2, varscan2
- KRTAP5-11 | c.78T>A p.S26= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV59369035; called by muse, mutect2, varscan2
- OR10Z1 | c.297C>T p.A99= | Silent (SNP) | VAF 124/557 reads (22%) | catalogued as COSV63524810; called by muse, mutect2, varscan2
- OR5T1 | c.804C>T p.L268= | Silent (SNP) | VAF 174/524 reads (33%) | catalogued as COSV57302679; called by muse, mutect2, varscan2
- PPP2R5D | c.705C>T p.I235= | Silent (SNP) | VAF 21/283 reads (7%) | catalogued as COSV55150655; called by muse, mutect2
- RYR3 | c.6225C>T p.N2075= | Silent (SNP) | VAF 51/286 reads (18%) | catalogued as rs1271989597, COSV66788575; called by muse, mutect2, varscan2
- SPEN | c.4359C>T p.S1453= | Silent (SNP) | VAF 77/255 reads (30%) | catalogued as COSV65361647; called by muse, mutect2, varscan2
- TLN2 | c.987G>T p.V329= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs369934703; called by muse, mutect2, varscan2
- TRIM25 | c.1632C>T p.R544= | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as COSV57544089; called by muse, mutect2, varscan2
- VWCE | c.1929G>A p.P643= | Silent (SNP) | VAF 42/135 reads (31%) | catalogued as rs192323431, COSV57112448; called by muse, mutect2, varscan2
- CHEK1 | c.*2del | 3'UTR (DEL) | VAF 6/62 reads (10%) | called by mutect2, varscan2
- GSPT1 | c.-63+161C>T | Intron (SNP) | VAF 18/48 reads (38%) | catalogued as COSV101341715; called by muse, varscan2
